Somatic mutation profile of tumor specimen MP2PRT-PAPJHB-TMP1-A (aliquot MP2PRT-PAPJHB-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPJHB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,005 days).
Specimen MP2PRT-PAPJHB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f2d437f-6466-4698-b249-14ecf9bd5eb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPJHB-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPJHB-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e724294e-fbd6-4e9f-b193-65938507f678

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 4, Frame Shift Ins 2, Intron 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 37/381 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALDH1A2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1179037754, COSV99990713; called by muse, mutect2
- ARHGAP6 | c.2635C>T p.R879W (on ENST00000337414 / NM_013427.3; = p.R676W on NM_013423.3) | Missense Mutation (SNP) | VAF 148/771 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV57293977; called by muse, mutect2, varscan2
- ATP10B | c.2929C>T p.R977C | Missense Mutation (SNP) | VAF 82/312 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs752814719, COSV59148132; called by muse, mutect2, varscan2
- CLDN9 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 146/478 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs573945523; called by muse, varscan2
- CSPG5 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as rs1174084216, COSV99273877; called by muse, mutect2, varscan2
- ERG | c.1109A>G p.D370G (on ENST00000398919 / NM_001243428.1; = p.D346G on NM_004449.4) | Missense Mutation (SNP) | VAF 32/846 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55729043; called by muse, mutect2
- FAM187A | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs897996915; called by muse, mutect2, varscan2
- MRGPRE | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 80/585 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370776661; called by muse, mutect2, varscan2
- MYO15A | c.6728C>T p.T2243M | Missense Mutation (SNP) | VAF 141/325 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs753611930, COSV52759746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEXMIF | c.594G>T p.Q198H | Missense Mutation (SNP) | VAF 205/479 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV50094245; called by muse, mutect2, varscan2
- NMRAL1 | c.623T>G p.V208G | Missense Mutation (SNP) | VAF 247/572 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV52060837; called by muse, mutect2, varscan2
- PALM | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 58/561 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs772962279, COSV52767005; ClinVar: uncertain significance; called by muse, mutect2
- PPFIA2 | c.3577C>T p.R1193C | Missense Mutation (SNP) | VAF 92/266 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs753248563, COSV61044910; called by muse, varscan2
- RBMXL3 | c.2237G>T p.R746L | Missense Mutation (SNP) | VAF 42/869 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.25); catalogued as rs201047008, COSV57746199; called by muse, mutect2
- SLC9A4 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as rs780812176, COSV54834743; called by muse, mutect2, varscan2
- SLIT1 | c.3925G>A p.G1309S | Missense Mutation (SNP) | VAF 85/353 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754930136, COSV56599792, COSV99822540; called by muse, mutect2, varscan2
- SSR4 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 68/531 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as rs149873632, COSV51245865, COSV51247402; called by muse, mutect2, varscan2
- TRIM7 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 173/489 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs748728945; called by muse, mutect2, varscan2
- TSGA10 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV61824870; called by muse, mutect2, varscan2
- ZNF319 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 194/458 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV54621441, COSV54623327; called by muse, mutect2, varscan2
- ADAMTS12 | c.1463_1464insGGGCTACCTT p.F488Lfs*26 | Frame Shift Ins (INS) | VAF 54/228 reads (24%) | called by mutect2, varscan2
- ANO4 | c.2289G>T p.R763S (on ENST00000392977 / NM_001286615.2; = p.R728S on NM_178826.4) | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CDCA2 | c.1837_1838insCCCGGGCTGG p.G613Afs*21 | Frame Shift Ins (INS) | VAF 54/232 reads (23%) | called by mutect2, pindel, varscan2
- COL4A6 | c.2068C>A p.P690T | Missense Mutation (SNP) | VAF 194/529 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRNN | c.557C>A p.S186Y | Missense Mutation (SNP) | VAF 135/370 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- LRRCC1 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 112/454 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MAMLD1 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 67/845 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAU2 | c.1583T>C p.L528P | Missense Mutation (SNP) | VAF 15/375 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADGRV1 | c.1497C>T p.S499= | Silent (SNP) | VAF 19/227 reads (8%) | catalogued as rs201377512, COSV67986307; called by muse, mutect2
- DIPK2B | c.1182C>G p.R394= | Silent (SNP) | VAF 26/811 reads (3%) | called by muse, mutect2
- GRPR | c.207G>A p.K69= | Silent (SNP) | VAF 203/530 reads (38%) | catalogued as rs1465222097; called by muse, mutect2, varscan2
- NLRP5 | c.846G>T p.V282= | Silent (SNP) | VAF 130/400 reads (33%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-1873A>C | Intron (SNP) | VAF 32/577 reads (6%) | called by muse, mutect2
- IGKV1D-16 | chr2:90100738 ins AC | 3'Flank (INS) | VAF 78/106 reads (74%) | called by mutect2, varscan2
- PABPC1P4 | n.93C>T | RNA (SNP) | VAF 108/390 reads (28%) | called by muse, mutect2, varscan2
